Surgical pathology report (de-identified scan), TCGA case TCGA-CR-6492, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-6492-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

- 1) MUCOSA, RIGHT DEEP MARGIN, EXCISION: INVOLVED BY SQUAMOUS CELL CARCINOMA.
- 2) SOFT TISSUE, POSTERIOR MUCOSAL MARGIN, EXCISION: SQUAMOUS MUCOSA WITH CHRONIC INFLAMMATION, NEGATIVE FOR MALIGNANCY.
- 3) SOFT TISSUE, LEFT MUCOSAL MARGIN, EXCISION: SQUAMOUS MUCOSA WITH CHRONIC INFLAMMATION, NEGATIVE FOR MALIGNANCY.
- 4) SOFT TISSUE, NEW DEEP RIGHT MARGIN, EXCISION: FIBROADIPOSE TISSUE, NEGATIVE FOR MALIGNANCY.
- 5) LYMPH NODE, RIGHT NECK LEVELS 2-5, EXCISION: 1 OF 33 LYMPH NODES INVOLVED BY SQUAMOUS CELL CARCINOMA, LARGEST FOCUS MEASURING 2.4 CM, (1/33), NEGATIVE FOR EXTRACAPSULAR EXTENSION.
- 6) SALIVARY GLAND AND LYMPH NODE, RIGHT NECK LEVEL 1, EXCISION: BENIGN SALIVARY GLAND, 4 LYMPH NODES NEGATIVE FOR MALIGNANCY (0/4).
- 7) PALATE, EXCISION: INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY TO POORLY-DIFFERENTIATED, 3.5 CM IN GREATEST DIMENSION, INVOLVING THE DEEP (BLACK) TISSUE EDGE; PERINEURAL INVASION PRESENT; BENIGN SALIVARY GLAND, (SEE COMMENT #1).
- 8) SOFT TISSUE, ADDITIONAL RIGHT DEEP MARGIN, EXCISION: BENIGN SALIVARY GLAND, NEGATIVE FOR MALIGNANCY, (SEE COMMENT #1).

COMMENT #1: Although tumor is present at the deep tissue edge of specimen #7, specimen #8 (additional R deep margin) supersedes this area, thus the final margin is negative for malignancy. These findings correspond to AJCC [REDACTED] Edition pathologic Stage III (pT2, pN1, pMn/a).

Upper Aerodigestive Tract-including Minor Salivary Glands, Lip, Oral cavity, Nasal Cavity, Paranasal Sinuses, Oropharynx, Nasopharynx, and Hypopharynx Summary of Findings:

Specimen Type: palatectomy with selective right neck level 1-5 dissection

Tumor Site: palate

[REDACTED]

[page 2 of 5]
Tumor Size: 3.5 cm

Laterality: Right

Margins: All final margins negative for malignancy.

Histologic Type: Squamous cell carcinoma

Histologic Grade: moderately to poorly differentiated

Pathologic Staging (pTMN) III

Primary tumor (pT): pT2

Regional Lymph Nodes (pN): pN1

Number examined: 33

Numbered involved: 1

Extracapsular extension: No

Perineural invasion: Yes

**Electronically Signed Out by [REDACTED]

CLINICAL DATA

Clinical Features: Unspecified

Operator: [REDACTED]

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1)deep right margin; 2)posterior mucosal margin; 3)left mucosal margin; 4)new deep right margin; 5)right neck levels 2-5; 6)right neck level 1; 7)palate; 8)additional right deep tissue

GROSS DESCRIPTION:

1) SOURCE: Deep Right Margin

The specimen is received fresh in a container labeled with the patient's name and medical record number along with the designation "deep right margin" and consists of a 0.6 x 0.5 x 0.2 cm piece of red soft tissue. The entire specimen is submitted for frozen section diagnosis.
Summary of sections: 1AFSC, entire specimen, 1/1.

2) SOURCE: Posterior Mucosal Margin

Received fresh and submitted for frozen section is a 3.5 x 0.2 x 0.1 cm piece of red-tan tissue with a mucosal surface. The tissue is submitted entirely for frozen section.
Summary of sections: 2AFSC, 1/1.

[REDACTED]

[page 3 of 5]
3) SOURCE: Left Mucosal Margin

Received fresh in a container and submitted for frozen section labeled "left mucosal margin" are 2 strips of tissue with a mucosal surface, each measuring 1.0 x 0.3 x 0.3 cm. The tissue is submitted entirely for frozen section.

Summary of sections: 3AFSC, 2/1.

4) SOURCE: New Deep Right Margin

The specimen is received fresh in a container labeled with the patient's name and medical record number, as well as the designation "new deep right margin" and consists of two pieces of cauterized red, soft tissue which measures 4.0 x 3.0 x 1.0 cm and 4.0 x 2.0 x 1.0 cm. The entire specimen is submitted for frozen section diagnosis.

Summary of sections: 4AFSC, tissue for frozen section diagnosis, 2/1.

5) SOURCE: Right Neck Levels 2-5

Received fresh labeled "right neck level 2-5 stitch superior" is a radical neck dissection with a possible submandibular gland, a stitch through the superior margin. The gland measures 3.0 x 2.5 x 2.0 cm. The remainder of the neck measures 10.0 x 6.0 x 2.2 cm. Multiple metallic clips are identified. No jugular vein is grossly identified attached to the specimen. The metallic clips are removed. The outer surface of the gland is inked. The cut surfaces of the submandibular gland are pale yellow-white, vaguely nodular with a cystic area measuring 1.4 x 1.0 x 0.7 cm. The cystic area contains brown-tan grumous material. Multiple candidate lymph nodes are recovered.

Summary of sections: 5A-5C, submandibular gland, 1/1 each, level 3 lymph nodes, superior to inferior 5D, 1 possible lymph node, 2/1; 5E, 1 possible lymph node, 2/1; 5F, 1 possible lymph node, 5/1; 5G, 2 possible lymph nodes, 2/1; level 4, superior to inferior possible candidate lymph nodes; 5H, 2 possible lymph nodes, 2/1; 5I, 1 possible lymph node bisected, 2/1; 5J, 1 possible lymph node bisected, 2/1; 5K, 1 possible lymph node trisected, 3/1; 5L, 1 possible lymph node bisected, 2/1; 5M, 2 possible lymph nodes, 2/1 each, level 5 lymph nodes superior to inferior 5N-5W, 1 possible lymph node in each cassette bisected, 2/1 each; 5X, 2 possible candidate lymph nodes, 2/1; 5Y, 1 lymph node bisected, 2/1.

6) SOURCE: Right Neck Level 1

Received fresh in a container labeled "right neck level 1" is a 5 cm x 3 cm x 2 cm piece of yellow lobulated tissue when palpated reveals 4 candidate lymph nodes. Bisecting these lymph nodes reveals a firm white area with a small portion of grossly normal appearing lymph node parenchyma.

Summary of sections: 6A, 2 lymph nodes bisected, 4/1; 6B, 1 bisected lymph node with 1 smaller lymph node, 3/1.

7) SOURCE: Palate

Received fresh in container labeled with patient's name, medical record number and palate, is a 4.5 x 4.0 x 1.2 cm palate excision. A stitch is placed to indicate the anterior margin. There is a 3.5 cm x 2.7 cm

[page 4 of 5]
exophytic lesion on the mucosal surface of the palate excision. This lesion is centrally located within the mucosal surface and is grossly 0.2 cm from the posterior margin as its closest margin. It is located 0.3 cm from anterior margin, 0.7 cm from superior margin, and 0.3 cm from inferior margin. The deep margin has significant cautery artifact. The specimen is inked in the following fashion: Deep cut surface black, anterior red, posterior orange, superior yellow, inferior blue.

Summary of sections: The specimen is then serially sectioned from anterior to posterior to reveal the exophytic mass extending into the deep tissue, abutting the black inked margin. Grossly, the specimen appears not to involve the remaining margin. Representative sections of each margin with closest tumor are submitted.

Summary of sections: 7A, anterior and posterior margin, 2/1; 7B, tumor to deep black margin, 2/1; 7C, tumor closest to yellow inked margin, 1/1; 7D, tumor closest to blue inked margin, 1/1; 7E, representative tumor to blue inked and black margin (this is not closest margin), 2/1.

8) SOURCE: Additional Right Deep Tissue

Received fresh in a container labeled "additional" are aggregates of tissue measuring 3.0 x 1.0 x 0.6 cm. The tissue has cautery artifact associated with submitted tissue. Tissue is submitted entirely over two cassettes. Summary of sections: 8A-8B, M/1 each.

Dictated by

Slides and report reviewed by Attending Pathologist.

SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Deep Right Margin

FROZEN SECTION DIAGNOSIS: INVOLVED BY SQUAMOUS CELL CARCINOMA.

2) SOURCE: Posterior Mucosal Margin

FROZEN SECTION DIAGNOSIS: BENIGN.

3) SOURCE: Left Mucosal Margin

FROZEN SECTION DIAGNOSIS: BENIGN.

4) SOURCE: New Deep Right Margin

FROZEN SECTION DIAGNOSIS: BENIGN.

[page 5 of 5]
Electronically signed by: [Redacted]

SNOMED: T-01000,T-01000,M-80103,

[Redacted]

[Redacted]

Source: NCI Genomic Data Commons file d55fb02f-22f2-4f5e-bd9f-de9cd98328d3 (TCGA-CR-6492.B0E618C4-A37C-4CEC-90D2-059312245712.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).